Surgical pathology report (de-identified scan), TCGA case TCGA-CZ-5462, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Harvard, specimen TCGA-CZ-5462-01A (Primary Tumor).

[page 1 of 2]
Accession Number: [REDACTED]
Type: Surgical Pathology
Specimen Type: Kidney, partial or total resection
Procedure Date: [REDACTED]
Ordering Provider: [REDACTED]

Report Status: Final

CASE: [REDACTED]
PATIENT: [REDACTED]

TCGA-CZ-5462

PATHOLOGIC DIAGNOSIS:

SPECIMEN DESIGNATED "RIGHT KIDNEY":

RENAL CELL CARCINOMA, clear cell type with focal sarcomatoid areas, Fuhrman nuclear grade III/IV (4.5 cm).
The tumor abuts but does not extend through the renal capsule.
The tumor shows extensive necrosis.
No lymphovascular invasion is seen.
The ureter, renal artery, and renal vein resection margins are negative for tumor.

The non-neoplastic kidney will be evaluated by Renal Pathology, and the findings will be reported in an addendum.
The AJCC Classification (6th Edition): T1b Nx M1 (including prior specimen, reviewed at [REDACTED]).

CLINICAL DATA:

History: None given.
Operation: None given.
Operative Findings: None given.
Clinical Diagnosis: None given.

TISSUE SUBMITTED:

A/1. Right kidney to frozen FS room for per. and tumor bank.

GROSS DESCRIPTION:

The specimen is received fresh, labeled with the patient's name, unit number, and "#1. Rt kidney", and consists of a right radical nephrectomy specimen (109.5-gram; 21.5 x 10.0 x 4.5 cm), to include: right kidney (9.0 x 7.5 x 4.2 cm), Gerota's fascia (10.5 x 4.5 x 0.2 cm), renal vein (0.8 cm in length x 0.8 cm in diameter), three renal arteries (ranging from 1.0 to 1.6 cm in length x 0.3 up to 0.7 cm in diameter), and ureter (5.5 cm in length x 0.3 cm in diameter). Within the upper pole, there is a golden yellow/red, hemorrhagic, encapsulated lobulated mass (4.5 x 4.3 x 3.6 cm), located 5.8 cm from the renal vein, 3.8 cm from the nearest renal artery, 9.0 cm from the ureteral margin, which grossly abuts the renal capsule but does not extend into the perinephric fat (inked black). Representative sections of the mass are submitted to cytogenetics, tissue bank, and for quick fix. Representative normal cortex is held for electron microscopy, immunofluorescence and tissue bank. The medullary pyramids are focally pale, however, the corticomedullary junction is distinct. There is moderate to severe atherosclerotic change of the renal arteries with up to 95% stenosis of the most inferior artery. The pelvis is grossly unremarkable. No lymph nodes are identified within the attached perinephric fat. Photographs are taken.

Micro A1: Renal vein, ureter, and renal artery margin (en face), 5 frags, [REDACTED]
Micro A2: "T1" (quick fix), 3 frags, [REDACTED]
Micro A3: "T2" (quick fix), 2 frags, [REDACTED]
Micro A4 and A5: Renal mass abutting capsule, 2 frags, [REDACTED]
Micro A6: Renal mass adjacent to medullary pyramid, 1 frag, [REDACTED]
Micro A7: Renal calyx/pelvis and corticomedullary junction, 1 frag, [REDACTED]

[page 2 of 2]
Accession Number: [REDACTED]

Report Status: Final

Type: Cytogenetics

CASE: [REDACTED]

Cytogenet: [REDACTED]

TCGA-CZ-5462

KARYOTYPE: Not obtained

METAPHASES COUNTED: 0 ANALYZED: 0 SCORED: 0 BANDING:

INTERPRETATION:

No metaphases were available from this specimen, therefore the cytogenetic analysis could not be performed.

INDICATION FOR TEST:

? Renal cell carcinoma

Source: NCI Genomic Data Commons file a820cf1b-3747-43b1-880d-275da542e8f3 (TCGA-CZ-5462.5333F5CB-150E-46B1-8BF2-9ADEE22CCC02.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).